HCMI case HCM-CSHL-0512-C24 — NCI Cancer Model Development for the Human Cancer Model Initiative (HCMI-CMDC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Other and unspecified parts of biliary tract. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0cafd069-029f-449d-97ce-b69009a80d80

Demographics
Sex at birth: female; Year of birth: 1943; Vital status: Alive.

Diagnoses (2)
1. Adenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8140/3; ICD-10 code: C24.1; Tissue or organ of origin: Ampulla of Vater; Classification of tumor: primary; Age at diagnosis: 76.0 years (27,746 days); AJCC staging edition: 8th; AJCC pathologic T: T3b; AJCC pathologic N: N2; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Prior treatment: No; Residual disease: R1; Sites of involvement: Lymph Node, Regional; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 16; Lymph nodes tested: 74; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: No.
   Treatment given: Treatment type: Surgery, NOS; Initial disease status: Initial Diagnosis; Days to treatment start: -11 days.
   Recorded as not given: neoadjuvant treatment (type not reported).
2. Adenocarcinoma, metastatic, NOS: ICD-O-3 morphology code: 8140/6; ICD-10 code: C77.2; Tissue or organ of origin: Ampulla of Vater; Site of resection or biopsy: Intra-abdominal lymph nodes; Classification of tumor: metastasis; Age at diagnosis: 76.0 years (27,746 days); Residual disease: R1; Tumor confined to organ of origin: No.
   Pathology details: Lymph nodes positive: 16; Lymph nodes tested: 74; Lymphatic invasion present: Yes; Perineural invasion present: Yes; Vascular invasion present: No.

Follow-up (3 entries)
- Days to follow up: 0 days; Progression or recurrence: Yes; Progression or recurrence type: Regional; Progression or recurrence anatomic site: Lymph node, NOS; Days to progression: 0 days.
- Days to follow up: 862 days (2.4 years); Disease response: Complete Response; Progression or recurrence: No.
- Follow-up contact recording only the day: day 27.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Weight: 88 kg; Height: 165 cm; BMI: 32.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Family history
- Relative with cancer history: no.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample HCM-CSHL-0512-C24-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
  Slide HCM-CSHL-0512-C24-06A-02-S1-HE: Section location: Top; Percent tumor cells: 40; Percent tumor nuclei: 50; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 60; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
  Slide HCM-CSHL-0512-C24-06A-02-S2-HE: Section location: Bottom; Percent tumor cells: 30; Percent tumor nuclei: 40; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 70; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample HCM-CSHL-0512-C24-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Whole Blood; Preservation method: Frozen.
- Samples HCM-CSHL-0512-C24-85N, HCM-CSHL-0512-C24-85O (2 with the same recorded description): Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
